Somatic mutation profile of tumor specimen TCGA-4V-A9QS-01A (aliquot TCGA-4V-A9QS-01A-11D-A423-09) from TCGA case TCGA-4V-A9QS, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 53.2 years (19,443 days).
Specimen TCGA-4V-A9QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94bcde15-81d3-4986-a4a2-aa1a8fc86108.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4V-A9QS-10A (Blood Derived Normal), aliquot TCGA-4V-A9QS-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f833ff7-2402-44cd-82a3-49c731b2910b

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV54023951; called by muse, mutect2
- ANGPTL1 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99327926; called by muse, mutect2, varscan2
- CD46 | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.051); called by muse, mutect2
- OR2T1 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- UHMK1 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF608 | c.1586G>A p.S529N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); called by muse, mutect2
- MTX3 | c.297C>A p.L99= | Silent (SNP) | VAF 15/158 reads (9%) | called by muse, mutect2
- SYN3 | c.1290C>T p.G430= | Silent (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
